NCICCR case DLBCL10478 — Genomic Variation in Diffuse Large B Cell Lymphomas (NCICCR-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/d41f1cb1-3803-43dc-b4ac-85513bfff558

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph node, NOS; Age at diagnosis: 47.0 years (17,155 days); Ann Arbor clinical stage: Stage II; Days to last follow up: 188 days; International Prognostic Index (IPI): Low Risk.

Biospecimens (1 sample)
- Sample DLBCL10478-sample: Sample type: Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Lymphocytes; Preservation method: Frozen.
